Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A816, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A816-01A (Primary Tumor).

Left adrenal: Pheochromocytoma

Date receiving:

Macroscopy

Two fragments were received.

The largest measures 4 x 2.7 x 2 cm corresponding to an adrenal tumor which contains tumor which arrived notched with a finely encapsulated aspect.

The second fragment measures 4 x 1 x 0.5 cm.

The adrenal tumor measure 3 x 3 cm long axis.

Microscopy

The histological examination of samples is performed on a tumoral proliferation finely encapsulated with two cellular contents, a contingent of large polygonal cells with abundant cytoplasm, basophilic, and nucleus finely nucleolated. These cells are arranged in a honeycomb structure or nests. Between these cells, a large vascular network is layed with another cellular type with more basophilic nucleus corresponding to sustentacular cells.

No vascular invasion, no capsule invasion, rare mitotic figures.

There is no evidence of tumor necrosis area.

The periadrenal fat is made of mature adipotic cells corresponding to cells with vacuolar cytoplasm (brown fat).

CONCLUSION

Benign pheochromocytoma

PASS score = 0

Translated on from the original pathological report evaluated on

ICD-O-3
Pheochromocytoma NOS 8700/0
Site (D) Adrenal gland NOS C74.9
JW 10/17/13

Case Is (c) (c) (c)		

Source: NCI Genomic Data Commons file 71d9d0b1-e129-4a7d-bdec-a0498edc281d (TCGA-WB-A816.C3C1C485-22E8-408B-B9B1-DF1964EE899E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).